National Lung Screening Trial (NLST) participant 126565 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 55 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 84): Negative screen, no significant abnormalities.
- T1: No screening result: Not Expected - Cancer in screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a negative screen; study year of the first confirmed lung cancer: T0; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 431, study year T0. Site: upper lobe of lung (ICD-O-3 C34.1), determined from cytology. Primary tumour location: left upper lobe. Histology: small cell carcinoma, NOS (ICD-O-3 8041/3). Grade: unspecified in pathology report. Tumour size on pathology: 27 mm. AJCC 6th edition staging: stage IV (best stage, from clinical TNM); clinical T4 N2 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical T4 N2 M1b. Summary stage: distant. VALCSG stage (the small-cell staging system; ACRIN recorded it for all its lung cancers): extensive.

Follow-up
Last known free of lung cancer: day 371.
